Gene-level copy-number profile of tumor specimen TCGA-23-1023-01R from TCGA case TCGA-23-1023, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.2 years (23,826 days).
Specimen TCGA-23-1023-01R: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.76fa62b1-c7f9-4264-a862-f0b66eae7966.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1023-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/2eff402c-60bf-441e-a9df-9b8f0316831f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 11,691; copy number 2: 38,052; copy number 3: 7,331; copy number 4: 1,158; copy number 5: 691; copy number 6: 749; copy number 7: 18; copy number 9: 25; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-23-1023-01): tumor purity 0.62, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–1): RSRP1.
- chr1:25,266,102–25,337,465, 4 genes: AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:64,450,096–64,461,381, 2 genes: AC008074.1, LGALSL.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr6:6,144,084–6,321,013, 1 gene (within-gene range 0–1): F13A1.
- chr6:6,346,465–6,622,771, 3 genes (within-gene range 0–1): LY86-AS1, SNAPC5P1, AL162719.1.
- chr6:32,812,763–32,820,466, 1 gene: HLA-DOB.
- chr6:139,240,061–139,291,998, 1 gene (within-gene range 0–2): TXLNB.
- chr9:7,304,551–7,478,320, 2 genes: AL157703.1, RPL4P5.
- chr12:53,739,611–53,898,976, 1 gene (within-gene range 0–1): AC076968.2.
- chr12:53,816,185–53,816,479, 1 gene: RN7SKP289.
- chr13:109,915,096–109,915,420, 1 gene: RN7SKP10.
- chr16:81,961,926–82,139,631, 6 genes (within-gene range 0–1): RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,484 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 5: RPL31P12.
- chr1:152,579,381–152,614,098, 3 genes, copy number 5: LCE3D, LCE3C, LCE3B.
- chr1:196,850,283–196,884,793, 1 gene, copy number 5 (within-gene range 2–5): BX248415.1.
- chr2:44,166,266–44,168,859, 2 genes, copy number 6: PDSS1P2, AC019129.2.
- chr2:88,857,161–94,738,249, 121 genes, copy number 5–9 (broad region; genes not listed).
- chr2:169,694,454–169,824,931, 7 genes, copy number 6: PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5.
- chr2:215,178,791–215,436,992, 5 genes, copy number 6: AC092844.1, LINC02862, ATIC, FN1, AC012462.3.
- chr2:218,125,289–218,659,655, 26 genes, copy number 5 (within-gene range 4–5): CXCR2, CXCR1, HMGB1P9, ARPC2, AC021016.1, GPBAR1, AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1, USP37, RN7SKP38, CNOT9, RNU6-136P, PLCD4, ZNF142.
- chr3:150,541,998–150,603,228, 2 genes, copy number 5: SERP1, EIF2A.
- chr3:150,611,262–150,611,877, 1 gene, copy number 5: AC069236.1.
- chr3:190,120,964–190,145,107, 1 gene, copy number 9: P3H2-AS1.
- chr4:150,970,671–150,970,782, 1 gene, copy number 7: RNA5SP168.
- chr5:77,784,881–77,786,003, 1 gene, copy number 5: ACTBP2.
- chr7:12,570,125–12,571,392, 1 gene, copy number 6: AC005281.1.
- chr8:62,863,082–62,864,181, 1 gene, copy number 9: SRPK2P.
- chr8:74,320,613–145,066,685, 1,097 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr9:105,710,290–105,710,781, 1 gene, copy number 5: AL592437.1.
- chr10:52,314,281–52,318,042, 1 gene, copy number 5: DKK1.
- chr11:128,522,390–128,522,449, 1 gene, copy number 7: MIR6090.
- chr13:48,316,863–48,328,564, 2 genes, copy number 6: PPP1R26P1, PCNPP5.
- chr14:18,333,726–19,976,659, 84 genes, copy number 5 (broad region; genes not listed).
- chr14:105,851,705–106,481,706, 119 genes, copy number 5 (broad region; genes not listed).
- chr17:46,193,576–46,268,694, 5 genes, copy number 6: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 11,433. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
